Somatic mutation profile of tumor specimen TCGA-59-2354-01A (aliquot TCGA-59-2354-01A-01W-0799-08) from TCGA case TCGA-59-2354, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3.
Specimen TCGA-59-2354-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c671478-f4a9-4c0f-9a7d-bd2a0678b93f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-59-2354-11A (Solid Tissue Normal), aliquot TCGA-59-2354-11A-01W-0800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9f7252b-3a30-4ae7-8677-cb8c223c8bb1

The open-access MAF lists 89 somatic variants for this specimen: 56 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 30, Nonsense Mutation 6, RNA 3, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PAH | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 101/287 reads (35%) | catalogued as rs5030846, CM900176, COSV61015179; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 37/87 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN3 | c.2614C>A p.R872S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV59748057; called by muse, mutect2, varscan2
- ADAM11 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99567936; called by muse, mutect2, varscan2
- ADAMTSL1 | c.5074G>T p.V1692L | Missense Mutation (SNP) | VAF 100/335 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV65883604; called by muse, mutect2, varscan2
- ANK1 | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV55877410; called by muse, mutect2, varscan2
- ANKRD17 | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 132/314 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58217898; called by muse, mutect2, varscan2
- BMPR1A | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.685); catalogued as COSV63135074; called by muse, mutect2, varscan2
- BTN3A1 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 150/365 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV50024595; called by muse, mutect2, varscan2
- C3orf22 | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV59072624; called by muse, mutect2, varscan2
- CCIN | c.1004C>A p.T335N | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV58724342; called by muse, mutect2, varscan2
- CEACAM1 | c.922T>G p.C308G | Missense Mutation (SNP) | VAF 423/630 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV50726041; called by muse, mutect2, varscan2
- CFAP43 | c.3781G>T p.E1261* | Nonsense Mutation (SNP) | VAF 136/527 reads (26%) | catalogued as COSV100829487, COSV63853049; called by muse, mutect2, varscan2
- CHD1 | c.5083G>C p.V1695L | Missense Mutation (SNP) | VAF 119/389 reads (31%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); catalogued as COSV99400042; called by muse, mutect2, varscan2
- CHD7 | c.8686T>C p.S2896P | Missense Mutation (SNP) | VAF 98/427 reads (23%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.91); catalogued as COSV71108358; called by muse, mutect2, varscan2
- CNTN1 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 76/283 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs201782849, COSV61636026; called by muse, mutect2, varscan2
- COL2A1 | c.4311del p.C1438Afs*33 | Frame Shift Del (DEL) | VAF 45/198 reads (23%) | catalogued as CD1210185; called by mutect2, pindel, varscan2
- DNAH10 | c.3514A>G p.T1172A (on ENST00000409039; = p.T1111A on NM_207437.3) | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV101292958; called by muse, mutect2, varscan2
- DNAH3 | c.1076T>G p.F359C | Missense Mutation (SNP) | VAF 135/377 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.49); catalogued as COSV99771242; called by muse, mutect2, varscan2
- FAM180A | c.377C>G p.T126R | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV58528167; called by muse, mutect2, varscan2
- HAUS6 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV100997842, COSV65839723; called by muse, mutect2, varscan2
- JPH3 | c.816G>T p.E272D | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV52465897; called by muse, mutect2, varscan2
- KCNAB1 | c.705G>A p.M235I (on ENST00000490337 / NM_172160.3; = p.M224I on NM_003471.3) | Missense Mutation (SNP) | VAF 81/327 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV56743325; called by muse, mutect2, varscan2
- LGI3 | c.1284C>A p.H428Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60443161; called by muse, mutect2, varscan2
- LRRC18 | c.70A>T p.I24F | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV53282711; called by muse, mutect2, varscan2
- MGAT5B | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 63/89 reads (71%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.799); catalogued as rs765152905, COSV56924443, COSV56927378; called by muse, mutect2, varscan2
- NEK10 | c.2593C>G p.P865A | Missense Mutation (SNP) | VAF 116/315 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs761822059, COSV99835769; called by muse, mutect2, varscan2
- NOL6 | c.3412G>C p.E1138Q | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); catalogued as COSV53044918, COSV99955312; called by muse, mutect2
- NTRK3 | c.1752T>A p.D584E | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100714156, COSV62299551; called by muse, mutect2, varscan2
- OLFML2B | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99669044; called by muse, mutect2, varscan2
- OR4K15 | c.377T>A p.F126Y (on ENST00000305051; = p.F102Y on NM_001005486.1) | Missense Mutation (SNP) | VAF 219/718 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59300812; called by muse, mutect2, varscan2
- OSBPL9 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as rs1330216668, COSV61868144, COSV61869338; called by muse, mutect2, varscan2
- PGAM4 | c.68G>A p.S23N | Missense Mutation (SNP) | VAF 91/252 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs1557229354, COSV100431896; called by muse, mutect2, varscan2
- PKHD1 | c.8173+1G>T p.X2725_splice | Splice Site (SNP) | VAF 99/496 reads (20%) | catalogued as COSV61861244, COSV61867482; called by muse, mutect2, varscan2
- PROX2 | c.1001T>A p.L334* | Nonsense Mutation (SNP) | VAF 43/126 reads (34%) | catalogued as COSV71520007; called by muse, mutect2, varscan2
- RAB6C | c.40T>C p.F14L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV101308578; called by mutect2, varscan2
- SHROOM4 | c.388T>A p.S130T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as COSV99174920; called by muse, mutect2, varscan2
- SLC26A6 | c.136C>A p.R46S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV50844235; called by muse, mutect2
- SLC26A9 | c.66T>A p.D22E | Missense Mutation (SNP) | VAF 58/311 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1253969296, COSV61601665; called by muse, mutect2, varscan2
- SLC36A4 | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV58395616; called by muse, mutect2, varscan2
- SLCO5A1 | c.2316G>C p.Q772H | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV52656494, COSV52662699; called by muse, mutect2, varscan2
- SPG7 | c.395A>G p.E132G | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as COSV99245540; called by muse, mutect2, varscan2
- STAT3 | c.158C>G p.A53G | Missense Mutation (SNP) | VAF 192/409 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52885539; called by muse, mutect2, varscan2
- STIP1 | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV59438461; called by muse, mutect2, varscan2
- SUPT5H | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 30/57 reads (53%) | catalogued as COSV63238838; called by muse, mutect2, varscan2
- TMCO2 | c.529G>C p.G177R | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV65646764; called by muse, mutect2, varscan2
- TNKS | c.3130C>T p.R1044W | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.892); catalogued as rs1170881389, COSV60054054; called by muse, mutect2, varscan2
- TTBK2 | c.3176G>A p.W1059* | Nonsense Mutation (SNP) | VAF 155/505 reads (31%) | catalogued as COSV51158119, COSV51158521; called by muse, mutect2, varscan2
- TTN | c.97334G>C p.R32445T (on ENST00000591111; = p.R25021T on NM_003319.4) | Missense Mutation (SNP) | VAF 66/232 reads (28%) | PolyPhen benign (0.358); catalogued as rs569650065, COSV59961308; called by muse, mutect2, varscan2
- TXNIP | c.973C>A p.P325T | Missense Mutation (SNP) | VAF 14/378 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100997345; called by muse, mutect2
- USP26 | c.1919C>G p.S640C | Missense Mutation (SNP) | VAF 109/341 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.852); catalogued as COSV63708310; called by muse, mutect2, varscan2
- ZNF415 | c.99T>G p.D33E | Missense Mutation (SNP) | VAF 219/380 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.284); catalogued as COSV54700087; called by muse, mutect2, varscan2
- CGRRF1 | c.826_828del p.V276del | In Frame Del (DEL) | VAF 79/506 reads (16%) | called by pindel, varscan2
- COL11A1 | c.4954_4971+10del p.X1652_splice | Splice Site (DEL) | VAF 56/224 reads (25%) | called by mutect2, pindel
- TRDV3 | c.316A>T p.S106C | Missense Mutation (SNP) | VAF 70/247 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- WDR11 | c.1063dup p.T355Nfs*14 | Frame Shift Ins (INS) | VAF 199/819 reads (24%) | called by pindel, varscan2
- ACAD11 | c.234T>C p.L78= | Silent (SNP) | VAF 56/216 reads (26%) | catalogued as COSV53894876; called by muse, mutect2, varscan2
- ADAMTS17 | c.2475C>G p.V825= | Silent (SNP) | VAF 31/137 reads (23%) | catalogued as COSV99172402; called by muse, mutect2, varscan2
- BEND3 | c.195G>C p.L65= | Silent (SNP) | VAF 47/140 reads (34%) | catalogued as COSV64680616; called by muse, mutect2, varscan2
- CD163L1 | c.3795C>T p.G1265= | Silent (SNP) | VAF 225/759 reads (30%) | catalogued as COSV58013449; called by muse, mutect2, varscan2
- CLSTN2 | c.375G>A p.Q125= | Silent (SNP) | VAF 177/599 reads (30%) | catalogued as COSV101515946; called by muse, mutect2, varscan2
- CRY1 | c.708A>G p.R236= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV50481601; called by muse, mutect2, varscan2
- FZD2 | c.804A>G p.V268= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV59528452; called by muse, mutect2, varscan2
- GALNTL6 | c.711C>A p.V237= | Silent (SNP) | VAF 60/148 reads (41%) | catalogued as COSV72490196; called by muse, mutect2, varscan2
- HIP1 | c.2088C>G p.A696= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV61184533; called by muse, mutect2, varscan2
- HLX | c.54G>T p.S18= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV65044578; called by muse, varscan2
- IGHD | c.33C>A p.I11= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV101163057; called by muse, mutect2, varscan2
- IGHV3-13 | c.318C>T p.A106= | Silent (SNP) | VAF 115/354 reads (32%) | catalogued as rs1398683851; called by muse, mutect2, varscan2
- LY75 | c.1926C>G p.P642= | Silent (SNP) | VAF 63/172 reads (37%) | catalogued as rs201863337; called by muse, mutect2, varscan2
- MFSD14B | c.540C>T p.V180= | Silent (SNP) | VAF 229/990 reads (23%) | catalogued as COSV64700587; called by muse, mutect2, varscan2
- NOL6 | c.2043G>A p.L681= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV53040502; called by muse, mutect2, varscan2
- OLFML2B | c.801G>T p.L267= | Silent (SNP) | VAF 49/187 reads (26%) | catalogued as rs1199484737, COSV99669047; called by muse, mutect2, varscan2
- OR2C1 | c.309C>T p.V103= | Silent (SNP) | VAF 42/158 reads (27%) | catalogued as rs373844589, COSV59239899; called by muse, mutect2, varscan2
- OR5J2 | c.501C>G p.S167= | Silent (SNP) | VAF 97/406 reads (24%) | catalogued as COSV56620547; called by muse, mutect2, varscan2
- PNLDC1 | c.1428G>C p.R476= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV51704557; called by muse, mutect2, varscan2
- PRKCE | c.843C>T p.H281= | Silent (SNP) | VAF 139/449 reads (31%) | catalogued as rs576600856, COSV60315454; called by muse, mutect2, varscan2
- PRRC2A | c.1689G>T p.V563= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV63224419; called by muse, mutect2, varscan2
- RPS8 | c.363G>T p.L121= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV63234362; called by muse, mutect2, varscan2
- SCUBE2 | c.1749T>C p.F583= | Silent (SNP) | VAF 313/889 reads (35%) | catalogued as COSV100497041; called by muse, mutect2, varscan2
- SIK3 | c.2592A>C p.P864= (on ENST00000445177 / NM_001366686.2; = p.P822= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as COSV99408979; called by muse, mutect2, varscan2
- SLC45A4 | c.2190G>A p.L730= (on ENST00000517878 / NM_001286646.2; = p.L679= on NM_001080431.2) | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- SYMPK | c.1341G>A p.K447= | Silent (SNP) | VAF 137/205 reads (67%) | catalogued as COSV55610527; called by muse, mutect2, varscan2
- SYNGAP1 | c.378C>T p.F126= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV53379641; called by muse, mutect2, varscan2
- VDR | c.438C>G p.T146= | Silent (SNP) | VAF 62/208 reads (30%) | catalogued as rs543098804, COSV57467510; called by muse, mutect2, varscan2
- VWA3B | c.3432T>A p.P1144= | Silent (SNP) | VAF 79/244 reads (32%) | catalogued as COSV71365235; called by muse, mutect2, varscan2
- WDR47 | c.360T>C p.C120= | Silent (SNP) | VAF 42/155 reads (27%) | catalogued as COSV100728483; called by muse, mutect2, varscan2
- AL353804.6 | n.25T>G | RNA (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- OR3A4P | n.599G>A | RNA (SNP) | VAF 140/353 reads (40%) | catalogued as rs747682187; called by muse, mutect2, varscan2
- SNORD114-26 | n.16C>A | RNA (SNP) | VAF 133/391 reads (34%) | called by muse, mutect2, varscan2
